Gene-level copy-number profile of tumor specimen TCGA-AX-A3FV-01A from TCGA case TCGA-AX-A3FV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 62.3 years (22,752 days).
Specimen TCGA-AX-A3FV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a41d3c1d-d709-45fb-999f-f98c2b8ff793.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3FV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd1e6532-a66c-470d-93b3-75d2190cdb39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 108; copy number 1: 3,694; copy number 2: 23,644; copy number 3: 19,312; copy number 4: 9,277; copy number 5: 3,289; copy number 6: 204; copy number 7: 152; copy number 8: 110; copy number 9: 10; copy number 11: 4; copy number 12: 2; copy number 14: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A3FV-01A-11D-A227-01): tumor purity 0.94, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:85,318,481–85,600,734, 8 genes (within-gene range 0–2): DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1.
- chr10:87,945,502–88,584,530, 5 genes (within-gene range 0–2): RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr14:18,333,726–19,957,996, 83 genes (broad region; genes not listed).
- chr14:28,264,390–28,765,292, 7 genes (within-gene range 0–3): BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1.
- chr15:44,562,696–44,767,829, 5 genes (within-gene range 0–1): SPG11, PATL2, Y_RNA, B2M, TRIM69.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,779 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,963,954–21,176,888, 465 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:32,457,835–33,512,743, 39 genes, copy number 5: RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1.
- chr1:149,903,318–150,913,292, 45 genes, copy number 6 (within-gene range 3–6): SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2.
- chr1:195,747,024–199,080,975, 44 genes, copy number 5: AL353709.1, LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1, AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1.
- chr1:214,281,102–215,394,418, 14 genes, copy number 6: SMYD2, AL929236.1, PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1.
- chr1:236,549,005–240,776,824, 58 genes, copy number 6–7 (within-gene range 4–7): HEATR1, ACTN2, MTR, RPSAP21, RPL35P1, MT1HL1, AL359259.1, RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr1:240,823,006–240,998,794, 3 genes, copy number 7: RFKP1, HNRNPA1P42, AL590682.1.
- chr2:160,141,981–160,271,888, 1 gene, copy number 5 (within-gene range 3–5): AC092153.1.
- chr3:8,359,344–8,366,427, 2 genes, copy number 6: AC023481.1, RNU4ATAC17P.
- chr3:17,157,162–18,444,817, 1 gene, copy number 7 (within-gene range 3–7): TBC1D5.
- chr3:17,664,963–18,445,588, 9 genes, copy number 7: RNU7-10P, AC104451.1, AC104451.2, AC104297.1, PDCL3P3, AC132807.1, AC132807.2, SATB1, AC144521.1.
- chr3:18,538,673–18,539,899, 1 gene, copy number 7: RAD23BP1.
- chr3:107,834,586–108,222,435, 6 genes, copy number 5: LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57.
- chr4:31,997,376–32,228,543, 1 gene, copy number 7 (within-gene range 1–7): LINC02506.
- chr4:32,351,038–32,353,220, 1 gene, copy number 7: LINC02353.
- chr5:3,452,816–4,440,259, 8 genes, copy number 5: LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3.
- chr5:4,512,262–4,648,254, 2 genes, copy number 5 (within-gene range 4–5): AC106799.1, AC010634.1.
- chr5:36,485,343–36,485,440, 1 gene, copy number 6: RNA5SP181.
- chr7:48,660,125–57,837,046, 216 genes, copy number 5–6 (broad region; genes not listed).
- chr7:123,452,193–125,933,832, 35 genes, copy number 5: IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93, AC003975.1.
- chr8:90,958,471–141,662,209, 705 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr9:7,177,577–10,612,723, 9 genes, copy number 8–9 (within-gene range 2–12): AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, PTPRD.
- chr9:8,936,079–36,487,548, 449 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr10:70,247,329–70,602,759, 9 genes, copy number 6: NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1, PRF1.
- chr11:21,260,061–21,383,909, 3 genes, copy number 6: AC090857.2, AC099730.1, RNA5SP337.
- chr11:47,239,302–54,725,816, 124 genes, copy number 5 (broad region; genes not listed).
- chr11:121,101,243–121,928,976, 9 genes, copy number 6 (within-gene range 4–6): TECTA, AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1, AP001977.1.
- chr12:66,767–34,249,958, 850 genes, copy number 5 (broad region; genes not listed).
- chr12:55,662,337–56,596,193, 74 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:59,964,942–63,594,640, 69 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr15:73,978,926–74,047,827, 3 genes, copy number 5: STOML1, PML, AC013486.1.
- chr15:75,251,743–75,786,898, 38 genes, copy number 7: NIFKP4, GOLGA6C, RN7SL489P, GOLGA6D, RN7SL327P, DNM1P34, ANP32BP1, COMMD4, AC068338.3, NEIL1, MIR631, MAN2C1, AC068338.2, SIN3A, RPL13P4, AC105137.1, AC105137.2, PTPN9, AC105036.2, AC105036.1, AC105036.3, SNUPN, AC105020.3, AC105020.2, IMP3, AC105020.6, AC105020.5, SNX33, CSPG4, AC105020.4, AC105020.1, ODF3L1, DNM1P35, AC019294.2, PPIAP47, AC019294.3, MIR4313, AC019294.1.
- chr19:39,125,770–39,182,816, 1 gene, copy number 5 (within-gene range 4–5): PAK4.
- chr19:39,196,964–48,170,603, 473 genes, copy number 5 (broad region; genes not listed).
- chr20:5,890,055–6,039,856, 11 genes, copy number 6 (within-gene range 3–6): RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P.

Autosomal genes at a single copy (total copy number 1): 3,673. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
